Somatic mutation profile of tumor specimen C3L-00999-01 (aliquot CPT0123260009) from CPTAC case C3L-00999, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 56.2 years (20,513 days).
Specimen C3L-00999-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcb7a8ba-053b-449c-a832-f569c51dc154.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00999-31 (Blood Derived Normal), aliquot CPT0124780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1b95788-0aa0-4201-b67d-f0a26595a159

The open-access MAF lists 179 somatic variants for this specimen: 116 protein-altering or splice-affecting, 40 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 40, Intron 9, Nonsense Mutation 9, 5'UTR 5, 5'Flank 4, Splice Site 3, 3'UTR 3, RNA 2, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 143/755 reads (19%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.760A>T p.I254F | Missense Mutation (SNP) | VAF 31/363 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52784505, COSV52825280, COSV52872554, COSV52987059; called by muse, mutect2
- TP53 | c.653T>A p.V218E | Missense Mutation (SNP) | VAF 37/382 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52690974, COSV52712839, COSV52761003; called by muse, mutect2
- AFF1 | c.3202G>C p.D1068H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100320393; called by muse, varscan2
- AHNAK2 | c.15388G>A p.E5130K | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.018); catalogued as rs776069775; called by muse, mutect2, varscan2
- ATM | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs768874297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.244); catalogued as rs564272797, COSV63519452; called by muse, mutect2
- BAIAP3 | c.2189C>T p.S730F | Missense Mutation (SNP) | VAF 35/572 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.087); catalogued as rs933403288; called by muse, mutect2
- BOD1L1 | c.6013G>A p.G2005R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.683); catalogued as rs201815629; called by muse, mutect2
- C4B | c.3347C>G p.S1116W | Missense Mutation (SNP) | VAF 68/1106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767540386, COSV70313250; called by muse, mutect2
- CA2 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53407676; called by muse, mutect2
- CARD11 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.119); catalogued as COSV67800673; called by muse, mutect2, varscan2
- CCNQ | c.402C>G p.F134L | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52345954; called by muse, mutect2, varscan2
- CELF1 | c.992G>A p.G331D (on ENST00000358597 / NM_001376422.1; = p.G327D on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs1222278365, COSV60111298; called by muse, mutect2
- CFH | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as CM060895, CM070672, COSV66407688; called by muse, mutect2
- CORIN | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.732); catalogued as COSV99903401; called by muse, mutect2, varscan2
- DGCR8 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as rs372966213; called by muse, mutect2
- DMXL1 | c.2690-1G>T p.X897_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as COSV60705910; called by muse, mutect2, varscan2
- DOCK9 | c.4133A>G p.Y1378C (on ENST00000376460 / NM_001366676.2; = p.Y1379C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1336238089; called by muse, mutect2
- DSCAML1 | c.1757G>T p.C586F (on ENST00000321322; = p.C526F on NM_020693.4) | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58389170; called by muse, mutect2, varscan2
- EFCAB13 | c.1158G>C p.K386N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV100516469; called by muse, mutect2
- EML3 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs551291197, COSV53871077; called by muse, mutect2, varscan2
- FANCG | c.1804C>A p.P602T | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as CD030332; called by muse, mutect2
- FOXI2 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as COSV59094738; called by muse, mutect2
- GPAA1 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1002623580, COSV100284086; called by muse, mutect2
- ILDR2 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99613250; called by muse, mutect2
- IQUB | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 36/225 reads (16%) | catalogued as COSV61238139; called by muse, mutect2, varscan2
- ITGA7 | c.2993C>T p.T998M (on ENST00000555728; = p.T954M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/347 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs142361411; ClinVar: uncertain significance; called by muse, mutect2
- LAMA4 | c.5030G>A p.R1677H (on ENST00000230538 / NM_001105206.3; = p.R1670H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782174781, COSV57892755; ClinVar: uncertain significance; called by muse, mutect2
- METTL7A | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs1239733714, COSV100153707; called by muse, mutect2, varscan2
- NGLY1 | c.1385C>A p.S462* | Nonsense Mutation (SNP) | VAF 9/140 reads (6%) | catalogued as COSV54992192; called by muse, mutect2
- NLRP1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs373530609; called by muse, mutect2
- NOM1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs762182460; called by mutect2, varscan2
- NOTCH1 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 39/490 reads (8%) | catalogued as COSV99490017; called by muse, mutect2
- NOTCH1 | c.1614G>C p.K538N | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.688); catalogued as COSV53082664; called by muse, mutect2
- NTRK3 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100447857; called by muse, mutect2
- OR6K6 | c.146A>G p.H49R (on ENST00000368144; = p.H25R on NM_001005184.1) | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100933666; called by muse, mutect2
- PAMR1 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as rs1214597437; called by muse, mutect2
- PCDHA7 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV65338739; called by muse, mutect2
- PPP1R15A | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 28/405 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538298636; called by muse, mutect2
- PSG5 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as rs200887046, COSV61653934; called by muse, mutect2
- RS1 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs61753173, CM992433, COSV66107036; ClinVar: not provided; called by muse, mutect2, varscan2
- SCAP | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs372044719; called by muse, mutect2, varscan2
- SIPA1L3 | c.3623T>A p.L1208Q | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as rs1479683726; called by muse, mutect2
- SNAI1 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 27/318 reads (8%) | catalogued as rs1270380770, COSV99723893; called by muse, mutect2
- SPINT3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/259 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs1313122392; called by muse, mutect2, varscan2
- TCHP | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as rs1391399511; called by muse, mutect2, varscan2
- TENM1 | c.3634G>A p.D1212N | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949199, COSV64446915; called by muse, mutect2
- THSD7A | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs779142301, COSV70264148, COSV70268650; called by muse, mutect2, varscan2
- TMEM132D | c.1196T>G p.V399G | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV70623175; called by muse, mutect2
- TMEM81 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1422904664; called by muse, mutect2
- TTN | c.100255G>A p.E33419K (on ENST00000591111; = p.E25995K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | PolyPhen possibly damaging (0.737); catalogued as COSV60387473; called by muse, mutect2
- TTN | c.59302G>A p.E19768K (on ENST00000591111; = p.E12344K on NM_003319.4) | Missense Mutation (SNP) | VAF 33/365 reads (9%) | PolyPhen benign (0.033); catalogued as COSV60380357; called by muse, mutect2
- TULP4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV100893937; called by muse, mutect2
- UGGT2 | c.2338A>C p.T780P | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV65075068; called by muse, mutect2, varscan2
- UNC5D | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); catalogued as rs780001315, COSV54831447; called by muse, mutect2, varscan2
- VPS13B | c.4423C>T p.H1475Y | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770616277; called by muse, mutect2
- XKR4 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV59314601; called by muse, mutect2
- ZBTB46 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.842); catalogued as COSV104368376; called by muse, mutect2, varscan2
- ZNF491 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV60057831; called by muse, mutect2
- AC011455.2 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 50/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATXN2 | c.2881C>T p.P961S (on ENST00000550104; = p.P801S on NM_002973.4) | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC115 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- CFAP161 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- COL5A1 | c.4819G>T p.G1607C | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CPLX1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- CUEDC1 | c.339C>T p.I113= | Splice Region (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- DAB2 | c.687+1G>A p.X229_splice | Splice Site (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- DBT | c.676A>G p.M226V | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- DEFB125 | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- DPP4 | c.1468+2T>C p.X490_splice | Splice Site (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- DSCAM | c.4814G>A p.G1605E | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.235); called by muse, mutect2
- DYNC1H1 | c.9059T>C p.L3020P | Missense Mutation (SNP) | VAF 38/604 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FAM110B | c.222dup p.V75Rfs*53 | Frame Shift Ins (INS) | VAF 23/224 reads (10%) | called by mutect2, pindel, varscan2
- FAM135A | c.2710G>T p.D904Y (on ENST00000370479 / NM_001351599.1; = p.D691Y on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- FBXL18 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJA1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2
- GLUD1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- GPRASP1 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- ITGAV | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KDM4C | c.2189A>G p.Y730C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KLHL29 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.042); called by muse, mutect2
- LAMA2 | c.5276G>C p.G1759A | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LAMA3 | c.1134G>C p.L378F | Missense Mutation (SNP) | VAF 38/418 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2
- LRRC19 | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- LRRK2 | c.3275A>T p.Y1092F | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MED23 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2
- MIDEAS | c.2752C>T p.L918F | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MOV10 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- MTHFD1L | c.2063G>A p.G688D | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH10 | c.2067A>C p.K689N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO9A | c.4445C>G p.S1482C | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- NALCN | c.4807C>A p.Q1603K | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.136); called by muse, mutect2
- NPFFR2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); called by muse, mutect2
- NPR3 | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- NSUN4 | c.487T>A p.L163M | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2
- P2RX4 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2
- PCLO | c.14043C>A p.S4681R | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2
- POP1 | c.1725G>A p.M575I | Missense Mutation (SNP) | VAF 14/383 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2
- PUS3 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- RASEF | c.1581C>A p.D527E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- RUFY1 | c.1803G>C p.K601N | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- SH3GL1 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 64/718 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- SHROOM3 | c.2695G>C p.E899Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.825); called by mutect2, varscan2
- SPAG17 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STRIP2 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D4 | c.2819G>T p.R940I | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TCF3 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.039); called by muse, mutect2
- TCTN1 | c.1436C>G p.A479G (on ENST00000551590 / NM_001173975.3; = p.A465G on NM_024549.6) | Missense Mutation (SNP) | VAF 37/430 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2
- TNFRSF10B | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTLL8 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2
- VWDE | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.113); called by muse, mutect2
- ZNF292 | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- ZNF541 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2
- ZNF679 | c.663C>A p.F221L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF79 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- ABCC10 | c.3319C>T p.L1107= (on ENST00000372530 / NM_001198934.2; = p.L1079= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/222 reads (8%) | catalogued as COSV99767032; called by muse, mutect2
- ACIN1 | c.2266C>T p.L756= | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- APOBR | c.2760G>A p.R920= (on ENST00000431282; = p.R929= on NM_018690.4) | Silent (SNP) | VAF 23/310 reads (7%) | called by muse, mutect2
- ATP1A2 | c.1275C>T p.L425= | Silent (SNP) | VAF 37/437 reads (8%) | catalogued as rs1336224465; called by muse, mutect2
- BAZ1B | c.96C>T p.F32= | Silent (SNP) | VAF 24/624 reads (4%) | called by muse, mutect2
- BOD1L1 | c.201C>T p.F67= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- C3 | c.4602C>T p.D1534= | Silent (SNP) | VAF 38/492 reads (8%) | called by muse, mutect2
- CACNG1 | c.492C>A p.R164= | Silent (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- CISH | c.681C>T p.C227= (on ENST00000348721 / NM_145071.4; = p.C244= on NM_013324.6) | Silent (SNP) | VAF 21/211 reads (10%) | catalogued as rs1559477651, COSV62294702; called by muse, mutect2
- CSNK1A1L | c.99G>C p.L33= | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- DENND1C | c.1719C>T p.S573= | Silent (SNP) | VAF 28/388 reads (7%) | catalogued as rs528598134, COSV57568712; called by muse, mutect2
- DYRK1B | c.447G>A p.L149= | Silent (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- ECM2 | c.1713C>T p.I571= | Silent (SNP) | VAF 19/317 reads (6%) | catalogued as rs373764507; called by muse, mutect2
- GET4 | c.219C>T p.F73= | Silent (SNP) | VAF 55/343 reads (16%) | catalogued as rs200321114; called by muse, mutect2, varscan2
- GTF3C4 | c.1596C>T p.N532= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- HID1 | c.522C>T p.V174= | Silent (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- HMX1 | c.63C>T p.I21= | Silent (SNP) | VAF 15/230 reads (7%) | called by muse, mutect2
- ITGA2B | c.33C>G p.L11= | Silent (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- KDM5D | c.1680C>T p.L560= | Silent (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- KLB | c.2982G>A p.K994= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- LGI4 | c.1179C>T p.T393= | Silent (SNP) | VAF 19/379 reads (5%) | catalogued as rs781216023, COSV100032385, COSV59532512; called by muse, mutect2
- LZTS2 | c.255C>A p.V85= | Silent (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- MAP4K1 | c.192C>T p.L64= | Silent (SNP) | VAF 26/385 reads (7%) | catalogued as COSV50264138; called by muse, mutect2
- MGA | c.2781G>A p.Q927= | Silent (SNP) | VAF 25/250 reads (10%) | catalogued as COSV54950236; called by muse, mutect2, varscan2
- P2RX5 | c.27C>G p.L9= | Silent (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- PKHD1 | c.9471C>T p.A3157= | Silent (SNP) | VAF 43/395 reads (11%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.2751G>C p.L917= | Silent (SNP) | VAF 19/206 reads (9%) | called by muse, mutect2
- PLXNC1 | c.2886C>T p.A962= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2
- PRM2 | c.108G>C p.L36= | Silent (SNP) | VAF 50/630 reads (8%) | called by muse, mutect2
- RAB11FIP1 | c.3405C>G p.S1135= | Silent (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- RGSL1 | c.93C>G p.L31= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- SCN10A | c.1600C>A p.R534= | Silent (SNP) | VAF 22/236 reads (9%) | catalogued as COSV71860392; called by muse, mutect2
- SEZ6L | c.2838G>A p.A946= | Silent (SNP) | VAF 24/424 reads (6%) | catalogued as rs369690932; called by muse, mutect2
- SPATA31A3 | c.3528A>T p.S1176= | Silent (SNP) | VAF 22/404 reads (5%) | called by muse, mutect2
- TH | c.1125C>T p.F375= (on ENST00000381178 / NM_199292.3; = p.F344= on NM_000360.4) | Silent (SNP) | VAF 33/502 reads (7%) | catalogued as rs763198914, CM093636; called by muse, mutect2
- TLN2 | c.1401C>T p.N467= | Silent (SNP) | VAF 36/476 reads (8%) | catalogued as rs773713515, COSV60897581; called by muse, mutect2
- TTN | c.40644C>T p.Y13548= (on ENST00000591111; = p.Y6124= on NM_003319.4) | Silent (SNP) | VAF 25/492 reads (5%) | catalogued as rs1455525236, CM112368; ClinVar: uncertain significance; called by muse, mutect2
- XIRP2 | c.7650A>G p.T2550= (on ENST00000628543; = p.T2725= on NM_152381.6) | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV54712617; called by muse, mutect2, varscan2
- XKR4 | c.1737C>T p.A579= | Silent (SNP) | VAF 34/324 reads (10%) | called by muse, mutect2, varscan2
- ZNF395 | c.1053C>T p.S351= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs375644952; called by muse, varscan2
- AC073316.1 | n.287+1741G>A | Intron (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2, varscan2
- ADCY6 | c.2443-21C>T | Intron (SNP) | VAF 18/376 reads (5%) | called by muse, mutect2
- ADH4 | c.-5G>C | 5'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- AL772337.1 | n.858-12G>A | Intron (SNP) | VAF 4/46 reads (9%) | catalogued as rs1173124580; called by muse, mutect2
- CBLN1 | c.-1G>T | 5'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- CD247 | c.-48G>A | 5'UTR (SNP) | VAF 49/416 reads (12%) | catalogued as rs559384801; called by muse, mutect2, varscan2
- CHRNA4 | c.*1732T>C | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- FIS1 | c.*8G>A | 3'UTR (SNP) | VAF 81/521 reads (16%) | catalogued as rs373285936; called by muse, mutect2, varscan2
- GZMB | c.55+110C>T | Intron (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- LIMCH1 | c.486+3632G>C | Intron (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- LINGO1-AS1 | n.352G>C | RNA (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- MAN2B1 | c.1310-16C>T | Intron (SNP) | VAF 28/357 reads (8%) | called by muse, mutect2
- MTFR1L | chr1:25820312 G>C | 5'Flank (SNP) | VAF 56/688 reads (8%) | called by muse, mutect2
- PIP4P1 | c.*198C>T | 3'UTR (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
- POMT1 | c.605+9G>C | Intron (SNP) | VAF 32/663 reads (5%) | called by muse, mutect2
- RGS8 | chr1:182672832 C>T | 5'Flank (SNP) | VAF 13/272 reads (5%) | called by muse, mutect2
- RHOF | chr12:121797593 G>C | 5'Flank (SNP) | VAF 25/287 reads (9%) | called by muse, mutect2
- SDC2 | c.-28G>T | 5'UTR (SNP) | VAF 47/291 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-3 | n.46A>T | RNA (SNP) | VAF 28/420 reads (7%) | called by muse, mutect2
- TFDP1 | c.1007-181G>T | Intron (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- TTN | c.6509-16C>A | Intron (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- USP14 | c.-18C>T | 5'UTR (SNP) | VAF 30/298 reads (10%) | called by muse, mutect2, varscan2
- VPS11 | chr11:119067886 G>T | 5'Flank (SNP) | VAF 43/272 reads (16%) | called by muse, mutect2, varscan2
